Somatic mutation profile of tumor specimen TCGA-AF-3911-01A (aliquot TCGA-AF-3911-01A-01D-1733-10) from TCGA case TCGA-AF-3911, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 48.2 years (17,609 days).
Specimen TCGA-AF-3911-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f063a5a0-ce42-4fc1-81b2-2532d2709026.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-3911-10A (Blood Derived Normal), aliquot TCGA-AF-3911-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4036579-2852-4899-a9c5-c2cf4994b0a9

The open-access MAF lists 95 somatic variants for this specimen: 70 protein-altering or splice-affecting, 25 silent.
By variant classification: Missense Mutation 59, Silent 25, Nonsense Mutation 6, Frame Shift Ins 2, Splice Region 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3956del p.P1319Lfs*2 | Frame Shift Del (DEL) | VAF 34/100 reads (34%) | catalogued as rs1057517558, COSV57356047, COSV57400437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.695T>A p.I232N | Missense Mutation (SNP) | VAF 51/79 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as CM103212, COSV52661257, COSV52760307, COSV52829354; called by muse, mutect2, varscan2
- AIMP2 | c.535C>G p.Q179E | Missense Mutation (SNP) | VAF 66/89 reads (74%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs750336358; called by muse, mutect2, varscan2
- ANXA7 | c.992G>A p.R331H (on ENST00000372919 / NM_001320880.2; = p.R309H on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/121 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs10159690; called by muse, mutect2, varscan2
- APC | c.1948G>T p.E650* | Nonsense Mutation (SNP) | VAF 37/108 reads (34%) | catalogued as CM930025; called by muse, mutect2, varscan2
- ASNSD1 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 28/85 reads (33%) | catalogued as rs187435985; called by muse, mutect2, varscan2
- ATP9B | c.3361G>A p.V1121M | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as rs778250195, COSV104410240; called by muse, mutect2, varscan2
- BEST4 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV100944051; called by muse, varscan2
- CARD11 | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs755425231, COSV62756075; called by muse, mutect2, varscan2
- CBR4 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs200095550; called by muse, mutect2, varscan2
- CRACD | c.2347G>A p.A783T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.063); catalogued as COSV51715979; called by muse, mutect2, varscan2
- DAB2IP | c.3442C>T p.L1148F (on ENST00000408936; = p.L1120F on NM_032552.3) | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV52262372; called by muse, mutect2, varscan2
- FGA | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV57393378; called by muse, mutect2, varscan2
- GNG11 | c.18C>G p.I6M | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.759); catalogued as rs370141216; called by muse, mutect2, varscan2
- GREM1 | c.346C>A p.R116S | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV55716233; called by muse, mutect2, varscan2
- GYS2 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs373682083; called by muse, mutect2, varscan2
- IGHG3 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.615); catalogued as rs587730662; called by muse, mutect2, varscan2
- IGSF8 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs768494086, COSV100081859; called by muse, mutect2
- ING1 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV58168157; called by muse, mutect2, varscan2
- KIAA1522 | c.3080G>A p.G1027D (on ENST00000373480 / NM_001198972.2; = p.G1086D on NM_020888.3) | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.295); catalogued as rs1458404772, COSV53865554; called by muse, mutect2, varscan2
- MAG | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs201757442, COSV62699874; called by muse, mutect2, varscan2
- METTL24 | c.715G>C p.V239L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs762926668; called by muse, mutect2, varscan2
- MYOM2 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316996365, COSV50707353; called by muse, mutect2, varscan2
- NCAM2 | c.22T>C p.Y8H | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.969); catalogued as rs1224629091; called by muse, mutect2, varscan2
- NLRC3 | c.1106G>A p.R369K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1202584963; called by muse, mutect2, varscan2
- OR4D6 | c.16C>A p.H6N | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV55660090; called by muse, mutect2, varscan2
- OR4D9 | c.621T>G p.S207R | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV61434930; called by muse, mutect2, varscan2
- OR7E24 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); catalogued as rs369925201; called by muse, mutect2, varscan2
- OXSR1 | c.1426G>A p.G476R | Missense Mutation (SNP) | VAF 125/238 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs766592272, COSV61259591; called by muse, mutect2, varscan2
- PAPSS1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs11555779, COSV54487662; called by muse, mutect2, varscan2
- PARD3B | c.3304C>T p.R1102W (on ENST00000406610 / NM_001302769.2; = p.R1033W on NM_057177.7) | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as rs369194609; called by muse, mutect2, varscan2
- POLR2B | c.2435G>T p.R812L | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58900274, COSV58901211; called by muse, mutect2, varscan2
- RFTN2 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); catalogued as COSV54385632; called by muse, mutect2, varscan2
- RNF133 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as rs537539023, COSV57369951; called by muse, mutect2, varscan2
- S1PR2 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759886451, COSV58485547; called by muse, mutect2, varscan2
- SLCO6A1 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as rs539137924, COSV65805537; called by muse, mutect2, varscan2
- TFAP2C | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.239); catalogued as rs748899621, COSV99571858; called by muse, mutect2, varscan2
- TRIM42 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53880822, COSV53883667; called by muse, mutect2, varscan2
- UNC79 | c.7392C>T p.T2464= (on ENST00000393151 / NM_001346218.2; = p.T2287= on NM_020818.5) | Splice Region (SNP) | VAF 52/114 reads (46%) | catalogued as COSV56394763; called by muse, mutect2, varscan2
- WDHD1 | c.2728C>T p.R910* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as rs778414691, COSV62216053; called by muse, mutect2, varscan2
- ZNF831 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as COSV64041816; called by muse, mutect2, varscan2
- ARHGAP30 | c.2165G>A p.G722D | Missense Mutation (SNP) | VAF 106/363 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ATP9B | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- BEST4 | c.697C>A p.P233T | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFHR5 | c.714T>A p.N238K | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- COG8 | c.820A>G p.T274A | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- DNAH11 | c.849G>C p.M283I | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FN1 | c.1935G>T p.W645C | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GART | c.1704A>G p.G568= | Splice Region (SNP) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- ICA1 | c.5_12dup p.K5Qfs*22 | Frame Shift Ins (INS) | VAF 46/336 reads (14%) | called by mutect2, varscan2
- KCNJ2 | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- KRT19 | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- LRGUK | c.1027T>G p.S343A | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC19 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MAGI1 | c.1539G>A p.M513I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.901); called by muse, varscan2
- MAP2 | c.4563A>T p.K1521N | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- NRXN3 | c.1521C>A p.F507L (on ENST00000335750 / NM_001330195.2; = p.F134L on NM_004796.6) | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PBK | c.265T>G p.L89V | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- PGK1 | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLC13A4 | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- SLC7A14 | c.1975G>T p.A659S | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SRCAP | c.8170A>G p.T2724A | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- STK40 | c.902A>T p.E301V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- SYNE1 | c.22925C>T p.A7642V (on ENST00000367255 / NM_182961.4; = p.A7571V on NM_033071.3) | Missense Mutation (SNP) | VAF 76/100 reads (76%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF6L | c.1208A>T p.Q403L | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- TECRL | c.887dup p.L297Pfs*6 | Frame Shift Ins (INS) | VAF 48/114 reads (42%) | called by mutect2, pindel, varscan2
- TMEFF1 | c.790A>T p.R264* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- ZIC2 | c.1155C>A p.H385Q | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.337); called by muse, mutect2
- ZNF646 | c.2854G>C p.D952H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- ZNF780A | c.931G>T p.G311W | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- AMER2 | c.294G>T p.T98= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV63438140, COSV63438429; called by muse, mutect2
- ASPN | c.786A>G p.K262= | Silent (SNP) | VAF 75/134 reads (56%) | called by muse, mutect2, varscan2
- ATP6V0D2 | c.96C>T p.D32= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs758425000; called by muse, mutect2, varscan2
- C14orf93 | c.1578G>A p.L526= | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2
- CHAMP1 | c.1209G>A p.T403= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as rs149624011; called by muse, mutect2, varscan2
- CRYBA1 | c.189C>A p.V63= | Silent (SNP) | VAF 39/130 reads (30%) | catalogued as rs375339782; called by muse, mutect2, varscan2
- DMXL2 | c.5742A>T p.T1914= | Silent (SNP) | VAF 47/129 reads (36%) | called by muse, mutect2, varscan2
- FCGBP | c.6612G>A p.A2204= | Silent (SNP) | VAF 50/252 reads (20%) | catalogued as rs772696382, COSV99662964, COSV99663282; called by muse, mutect2, varscan2
- GRIK3 | c.1189C>T p.L397= | Silent (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- JPH2 | c.843C>T p.A281= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs151305680; called by muse, mutect2, varscan2
- LILRB1 | c.1995C>T p.Y665= (on ENST00000427581; = p.Y614= on NM_006669.6) | Silent (SNP) | VAF 62/102 reads (61%) | catalogued as rs771848801, COSV61116369; called by muse, mutect2, varscan2
- ME3 | c.690C>T p.V230= | Silent (SNP) | VAF 37/69 reads (54%) | catalogued as rs781719661, COSV60165065; called by muse, mutect2, varscan2
- MMRN2 | c.2700T>A p.T900= | Silent (SNP) | VAF 43/82 reads (52%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.231C>T p.S77= | Silent (SNP) | VAF 27/44 reads (61%) | catalogued as rs776577056, COSV57107974; called by muse, mutect2, varscan2
- NAB2 | c.1053C>T p.A351= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as COSV55666842; called by muse, mutect2, varscan2
- OR4P4 | c.882C>T p.N294= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as rs754844051, COSV58923701; called by muse, mutect2, varscan2
- PCK1 | c.1083C>T p.A361= | Silent (SNP) | VAF 25/198 reads (13%) | catalogued as rs534949125, COSV60129295; called by muse, mutect2, varscan2
- PNMA3 | c.1059C>T p.A353= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- PRX | c.4185C>T p.G1395= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1259617945; called by muse, mutect2, varscan2
- RECK | c.1026C>A p.V342= | Silent (SNP) | VAF 17/119 reads (14%) | called by muse, mutect2, varscan2
- SDK1 | c.1863G>A p.T621= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs375345968; called by muse, mutect2
- SPTAN1 | c.276G>T p.V92= | Silent (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
- TMEM255A | c.351C>T p.H117= | Silent (SNP) | VAF 64/203 reads (32%) | called by muse, mutect2, varscan2
- ULK1 | c.2158C>T p.L720= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as COSV58856792; called by muse, mutect2, varscan2
- ZFHX3 | c.900C>T p.H300= | Silent (SNP) | VAF 35/239 reads (15%) | catalogued as rs150869238; called by muse, mutect2, varscan2
